Somatic mutation profile of tumor specimen TARGET-30-PARSBI-01A (aliquot TARGET-30-PARSBI-01A-01D) from TARGET case TARGET-30-PARSBI, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 6.5 years (2,390 days).
Specimen TARGET-30-PARSBI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9a30d49-85c9-4049-9ca9-40b97e7f6053.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARSBI-10A (Blood Derived Normal), aliquot TARGET-30-PARSBI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cbae2458-13e6-4489-895e-512b4833cf2e

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 14, Silent 7, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.9986A>T p.K3329M | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.896); catalogued as COSV71292196; called by muse, mutect2, varscan2
- BMERB1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.772); catalogued as rs764275264, COSV55510629; called by muse, mutect2
- GGPS1 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as rs1327563695, COSV51397570; called by muse, mutect2, varscan2
- KRT38 | c.1352C>G p.T451S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.093); catalogued as COSV55846999; called by muse, mutect2, varscan2
- LTN1 | c.1489A>G p.I497V | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV63734714; called by muse, mutect2, varscan2
- MAP3K2 | c.1360G>A p.A454T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as rs748193402, COSV61294473; called by muse, mutect2, varscan2
- MYRIP | c.1686G>T p.E562D | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV56876958; called by muse, mutect2, varscan2
- OR10G4 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 48/79 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57978050; called by muse, mutect2, varscan2
- P2RX2 | c.569C>G p.T190R (on ENST00000343948 / NM_170683.4; = p.T118R on NM_012226.5) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.198); catalogued as COSV57686459; called by muse, mutect2, varscan2
- PRAMEF10 | c.1358G>A p.G453D | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs772276554, COSV52435770; called by muse, mutect2, varscan2
- ROCK1 | c.3446A>G p.K1149R | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.866); catalogued as rs868384460, COSV67697826; called by muse, mutect2
- TRPC6 | c.1076G>A p.G359D | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV60258577; called by muse, mutect2, varscan2
- VNN2 | c.1187G>A p.R396K | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV58473550; called by muse, mutect2, varscan2
- RPSA | c.393C>A p.H131Q | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- VPS13A | c.4427_4434del p.T1476Ifs*2 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- ABCA10 | c.4242G>A p.V1414= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as rs768300766, COSV52226951; called by muse, mutect2, varscan2
- CCDC144A | c.2386C>T p.L796= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV60700387; called by muse, mutect2, varscan2
- CSF1R | c.1047C>T p.P349= | Silent (SNP) | VAF 75/180 reads (42%) | catalogued as rs753596113, COSV53839807; called by muse, mutect2, varscan2
- CYP11B2 | c.1161C>T p.S387= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV59997174; called by muse, mutect2, varscan2
- LCT | c.214C>T p.L72= | Silent (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- OR4Q3 | c.306T>G p.S102= | Silent (SNP) | VAF 21/101 reads (21%) | catalogued as COSV59179635; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.2157G>A p.L719= (on ENST00000259318 / NM_001136562.3; = p.L950= on NM_007203.5) | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as rs748069822, COSV52179583; called by muse, mutect2, varscan2
